Gene-level copy-number profile of specimen HCM-SANG-0296-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-0296-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0296-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 10a70a17-58e1-4b75-b7ed-053135fe643b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0296-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/24855818-eb7c-4a4f-8c60-651efa09c536

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 5; copy number 2: 50; copy number 3: 18,419; copy number 4: 16,423; copy number 5: 13,064; copy number 6: 6,563; copy number 7: 1,858; copy number 8: 1,957; copy number 9: 518; copy number 10: 10; copy number 11: 12; copy number 13: 3; copy number 16: 1.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:109,978,256–109,980,718, 1 gene: GPR6.
- chr9:267,966–273,002, 1 gene (within-gene range 0–4): AL158832.1.
- chr9:21,638,285–21,696,943, 2 genes: H3P30, KHSRPP1.
- chr9:21,802,636–22,128,103, 14 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 544 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–143,635,641, 3 genes, copy number 13: AC239859.1, NBPF17P, PFN1P12.
- chr1:143,736,066–143,739,506, 1 gene, copy number 16: AC239800.2.
- chr1:145,095,974–145,242,124, 6 genes, copy number 9: FAM72D, LINC01145, RNU1-153P, AC241585.2, AC241585.1, PPIAL4D.
- chr5:7,289,891–7,348,671, 4 genes, copy number 9 (within-gene range 7–9): AC091951.3, AC091951.1, AC027343.3, LINC02123.
- chr5:8,525,144–8,660,059, 6 genes, copy number 9: AC091953.1, AC091953.3, AC091953.5, MTND6P2, MTCYBP37, AC091953.2.
- chr5:9,035,033–9,546,075, 1 gene, copy number 9 (within-gene range 8–9): SEMA5A.
- chr5:9,363,275–9,903,852, 12 genes, copy number 9: AC091906.1, AC027335.2, SEMA5A-AS1, AC027335.1, SNHG18, SNORD123, AC026787.1, TAS2R1, LINC02112, RNA5SP177, AC091838.1, LINC02221.
- chr5:10,679,230–11,904,446, 4 genes, copy number 9 (within-gene range 8–9): DAP, AC012629.2, AC012629.1, CTNND2.
- chr5:12,297,399–12,297,504, 1 gene, copy number 9: RNU6-679P.
- chr5:12,574,830–14,664,604, 16 genes, copy number 9–10 (within-gene range 8–10): LINC01194, AC106794.2, AC106794.1, LINC02220, AC016553.1, RPS23P5, NENFP3, AC016546.1, DNAH5, AC016576.1, AC016549.1, OTULINL, AC010627.1, CCT6P2, EEF1A1P13, AC010491.1.
- chr5:14,704,800–15,384,853, 11 genes, copy number 9: ANKH, AC010491.2, RBBP4P1, MIR4637, AC016575.1, UQCRBP3, HNRNPKP5, SEPHS2P1, U8, LINC02149, MARK2P5.
- chr5:15,500,180–35,429,277, 252 genes, copy number 9–10 (broad region; genes not listed).
- chr5:35,852,695–45,895,970, 158 genes, copy number 9–11 (broad region; genes not listed).
- chr9:60,914,407–63,385,117, 66 genes, copy number 9 (broad region; genes not listed).
- chr19:27,638,483–27,794,005, 3 genes, copy number 9–10 (within-gene range 8–10): ERVK-28, AC112702.1, LINC00662.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
